CCDI case PBCEKG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other endocrine glands and related structures.
https://portal.gdc.cancer.gov/cases/33eba26f-177f-4fee-a70c-200c61733909

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Pineal gland; Age at diagnosis: 17.9 years (6,523 days).

Biospecimens (4 samples)
- Sample 0DPYDA: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DPYE0, 0DPYE7 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQC20: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
